Surgical pathology report (de-identified scan), TCGA case TCGA-61-2003, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2003-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OMENTAL CAKE, OMENTECTOMY –
HIGH GRADE SEROUS CARCINOMA.

PART 2: FALLOPIAN TUBE AND OVARY, LEFT, SALPINGO-OOPHORECTOMY –
HIGH GRADE SEROUS CARCINOMA INVOLVING THE LEFT OVARY AND LEFT FALLOPIAN TUBE.

PART 3: FALLOPIAN TUBE AND OVARY, RIGHT, SALPINGO-OOPHORECTOMY –
HIGH GRADE SEROUS CARCINOMA INVOLVING THE RIGHT OVARY AND RIGHT FALLOPIAN TUBE.

PART 4: UTERUS, SUPRACERVICAL HYSTERECTOMY (180 GRAMS) –
A. HIGH GRADE SEROUS CARCINOMA INVOLVING THE SEROSA OF THE UTERUS AND LOWER UTERINE
SEGMENT, LYMPHOVASCULAR SPACES, AND SEROSAL ADHESIONS.
B. LEIOMYOMAS, MEASURING 0.4 TO 2.6 CM IN GREATEST DIMENSION.
C. ADENOMYOSIS.
D. CERVIX WITH CHRONIC CYSTIC CERVICITIS AND TUBAL METAPLASIA.
E. PROLIFERATIVE PATTERN ENDOMETRIUM.

PART 5: TUMOR, CUL DE SAC, EXCISION –
HIGH GRADE SEROUS CARCINOMA.

PART 6: LYMPH NODES, LEFT PELVIC, EXCISION –
A. THREE OF FOUR LYMPH NODES, POSITIVE FOR METASTATIC CARCINOMA (3/4).
B. THE LARGEST FOCUS OF METASTATIC CARCINOMA MEASURES 1.7 CM.
C. EXTRACAPSULAR EXTENSION IS IDENTIFIED.

PART 7: OMENTUM, OMENTECTOMY –
HIGH GRADE SEROUS CARCINOMA.

PART 8: APPENDIX, APPENDECTOMY –
HIGH GRADE SEROUS CARCINOMA INVOLVING SEROSA OF APPENDIX AND SEROSAL ADHESIONS.

PART 9: MASS/TUMOR, PELVIC, EXCISION –
HIGH GRADE SEROUS CARCINOMA.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	TAH with salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 12.5 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE:	Moderately differentiated (6-7 pts)
ARCHITECTURAL PATTERN:	Papillary (2)
CYTOLOGIC ATYPIA:	Marked (3)
VASCULAR INVASION:	Yes
TUMOR CAPSULE:	Ruptured
SURFACE IMPLANTS:	Invasive
SURFACE IMPLANT SITE:	Uterus, Fallopian Tubes, Omentum
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 4
LYMPH NODES POSITIVE:	Number of positive lymph nodes, Right: 0 Number of positive lymph nodes, Left: 3
LYMPH NODE GROUPS INVOLVED:	Pelvic, Left
EXTRANODAL EXTENSION:	Yes
T STAGE, PATHOLOGIC:	pT3c
N STAGE, PATHOLOGIC:	pN1
M STAGE, PATHOLOGIC:	pMX
FIGO STAGE:	IIIC

Source: NCI Genomic Data Commons file cafb532a-14cb-4f0b-a118-4bd40a3b3f06 (TCGA-61-2003.79C66510-6E38-470F-9E91-D774665D39A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).